Somatic mutation profile of tumor specimen TCGA-AK-3440-01A (aliquot TCGA-AK-3440-01A-01W-0886-08) from TCGA case TCGA-AK-3440, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 58.4 years (21,337 days).
Specimen TCGA-AK-3440-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7926dd70-45d4-4b02-bdef-221ddd8eb5b2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AK-3440-10A (Blood Derived Normal), aliquot TCGA-AK-3440-10A-01D-0966-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a7b29931-0525-4199-960c-e617f99ede65

The open-access MAF lists 32 somatic variants for this specimen: 28 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Frame Shift Ins 6, Silent 3, Nonsense Mutation 1, In Frame Del 1, RNA 1, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.96+1G>T p.X32_splice | Splice Site (SNP) | VAF 209/250 reads (84%) | hotspot (GDC flag); catalogued as rs1131691003, CS167193, COSV52662718, COSV52757202, COSV53162510; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCC11 | c.3147G>T p.R1049S | Missense Mutation (SNP) | VAF 161/417 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.926); catalogued as rs1567490520; called by muse, mutect2, varscan2
- ASAP1 | c.2107G>A p.V703I | Missense Mutation (SNP) | VAF 34/396 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as rs754279639, COSV63050648; called by muse, mutect2
- CST9L | c.389C>T p.P130L | Missense Mutation (SNP) | VAF 145/331 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100980932; called by muse, mutect2, varscan2
- ELP4 | c.389C>T p.P130L | Missense Mutation (SNP) | VAF 63/159 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776621433; called by muse, mutect2, varscan2
- GCNT4 | c.880dup p.H294Pfs*2 | Frame Shift Ins (INS) | VAF 30/272 reads (11%) | catalogued as rs768450027; called by mutect2, varscan2
- GYS1 | c.1657C>T p.L553F | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV54401594; called by muse, mutect2
- IRS4 | c.1772dup p.K592Qfs*12 | Frame Shift Ins (INS) | VAF 28/150 reads (19%) | catalogued as rs780982673; called by mutect2, varscan2
- KIF5A | c.2512G>A p.E838K | Missense Mutation (SNP) | VAF 383/815 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.489); catalogued as COSV54052551; called by muse, mutect2, varscan2
- LTBP4 | c.4382G>A p.R1461H (on ENST00000308370 / NM_001042544.1; = p.R1424H on NM_003573.2) | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.474); catalogued as rs1178129446, COSV99180589; called by muse, mutect2, varscan2
- MAP7D3 | c.922dup p.Q308Pfs*25 | Frame Shift Ins (INS) | VAF 34/321 reads (11%) | catalogued as rs746202015; called by mutect2, varscan2
- NRXN1 | c.2566C>T p.R856W | Missense Mutation (SNP) | VAF 8/255 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs796052777, COSV58442242; ClinVar: uncertain significance; called by muse, mutect2
- PIK3C2B | c.859dup p.R287Pfs*38 | Frame Shift Ins (INS) | VAF 24/216 reads (11%) | catalogued as rs749506841; called by mutect2, varscan2
- RNF213 | c.5857dup p.Q1953Pfs*30 | Frame Shift Ins (INS) | VAF 4/31 reads (13%) | catalogued as rs768772409; called by pindel, varscan2
- SLITRK1 | c.1579C>T p.H527Y | Missense Mutation (SNP) | VAF 39/45 reads (87%) | SIFT tolerated (0.16); PolyPhen benign (0.031); catalogued as COSV65676591; called by muse, mutect2, varscan2
- TRPM3 | c.3115G>C p.E1039Q (on ENST00000357533 / NM_001366142.2; = p.E882Q on NM_020952.6) | Missense Mutation (SNP) | VAF 42/671 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.309); catalogued as COSV62593784; called by muse, mutect2
- ABCC11 | c.3146G>T p.R1049M | Missense Mutation (SNP) | VAF 160/414 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- ANXA3 | c.770G>T p.R257I | Missense Mutation (SNP) | VAF 192/494 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.743); called by muse, mutect2, varscan2
- BNIP5 | c.96G>A p.W32* | Nonsense Mutation (SNP) | VAF 137/168 reads (82%) | called by muse, mutect2, varscan2
- COL13A1 | c.1550dup p.G518Rfs*167 (on ENST00000398978 / NM_001130103.2; = p.G461Rfs*152 on NM_080798.4 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 4/28 reads (14%) | called by pindel, varscan2
- CSMD3 | c.3733G>A p.A1245T (on ENST00000297405 / NM_001363185.1; = p.A1141T on NM_052900.3) | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.011); called by muse, mutect2
- GEMIN8 | c.248G>T p.W83L | Missense Mutation (SNP) | VAF 198/212 reads (93%) | SIFT tolerated (0.65); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- JMJD7-PLA2G4B | c.41G>A p.R14Q | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.001); called by muse, mutect2
- RSPH3 | c.512G>A p.R171H (on ENST00000252655; = p.R29H on NM_031924.8) | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- TAT | c.170G>A p.R57Q | Missense Mutation (SNP) | VAF 62/121 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZMYM6 | c.1408G>T p.A470S | Missense Mutation (SNP) | VAF 8/130 reads (6%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.986); called by muse, mutect2
- ZNF628 | c.483del p.S162Afs*265 | Frame Shift Del (DEL) | VAF 22/62 reads (35%) | called by mutect2, pindel, varscan2
- ZNF79 | c.1019_1033del p.K340_C345delinsS | In Frame Del (DEL) | VAF 128/406 reads (32%) | called by mutect2, pindel, varscan2
- GABRG3 | c.1347C>T p.F449= | Silent (SNP) | VAF 55/103 reads (53%) | catalogued as COSV100409378; called by muse, mutect2, varscan2
- HERC2 | c.3453C>T p.L1151= | Silent (SNP) | VAF 145/295 reads (49%) | called by muse, mutect2, varscan2
- SAMD9 | c.1755A>G p.G585= | Silent (SNP) | VAF 10/330 reads (3%) | called by muse, mutect2
- MIR92A1 | n.73G>C | RNA (SNP) | VAF 37/51 reads (73%) | called by muse, mutect2, varscan2
